Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A6DF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A6DF-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Anterior bone marrow, biopsy
- No tumor seen

B: Anterior floor of mouth, biopsy
- No tumor seen

C: Anterior vestibule of mouth, biopsy
- No tumor seen

D: Lingual nerve margin, biopsy
- No tumor seen

E: Soft tissue, left face, biopsy
- Epidermal inclusion cyst
- No malignancy identified

F: Proximal nerve margin, biopsy
- No tumor seen

G: Proximal inferior alveolar nerve margin, biopsy
- No tumor seen

H: Mandible and floor of mouth, left, composite resection

Tumor histologic type/subtype: squamous cell carcinoma,
moderately differentiated

Primary site: left floor of mouth

Size: 7.2 cm

Extent of invasion:

Angiolymphatic invasion: not identified

Perineural Invasion: not identified

Bone invasion: present

P16 IHC status: weakly positive

HR HPV ISH status: negative

Carcinoma in situ: not identified

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site: Floor of mouth NOS
C04.9

JAS/21/13

[page 2 of 5]
Surgical Margins: negative, tumor is 0.1 cm from the closest margin (medial soft tissue, inked black correlate with operative findings)

Lymph nodes: no tumor seen in 28 lymph nodes (0/28; 2 in this specimen, see also specimens I-M)

AJCC PATHOLOGIC TNM STAGE: pT4a pN0

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

I: Lymph node, left level 2, removal
- No tumor seen in eight lymph nodes (0/8)

J: Lymph node, left level 3, removal
- No tumor seen in nine lymph nodes (0/9)

K: Lymph node, left level 4, removal
- No tumor seen in five lymph nodes (0/5)

L: Lymph node, left level 1B, biopsy
- No tumor seen in one lymph node (0/1)

M: Lymph node, level 1, removal
- No tumor seen in three lymph nodes (0/3)

Intraoperative Consult Diagnosis:

An intraoperative consultation is requested by Dr. from at
(A-E), F) and (G) on

FSA1: Anterior bone marrow, biopsy
- No tumor seen

FSB1: Anterior floor of mouth, biopsy
- No tumor seen

FSC1: Anterior vestibule of mouth, biopsy
- No tumor seen

FSD1: Lingual nerve margin, biopsy
- No tumor seen

FSE1: Soft tissue, left face, biopsy
- No tumor seen (acellular keratin is present)

[page 3 of 5]
FSF1: Proximal nerve margin, biopsy
- No tumor seen

FSG1: Proximal inferior alveolar nerve margin, biopsy
- No tumor seen

Dr. at (A-E), (F) and (G) on

Frozen Section Pathologist:, MD

Clinical History:
-year-old male with left mouth lesion.

Gross Description:

Specimen A is received in one appropriately labeled container, additionally labeled "anterior bone marrow" and holds a red/tan bony tissue fragment that measures 0.3 x 0.3 x 0.2 cm. The fragment is entirely frozen as FSA1,

Specimen B is received in one appropriately labeled container, additionally labeled "anterior floor of mouth" and holds a red/tan soft tissue fragment that measures 1.0 x 0.5 x 0.3 cm. The fragment is entirely frozen as FSB1,

Specimen C is received in one appropriately labeled container, additionally labeled "anterior vestibule of mouth" and holds a red/tan soft tissue fragment that measures 2.2 x 0.4 x 0.3 cm. The fragment is entirely frozen as FSC1,

Specimen D is received in one appropriately labeled container, additionally labeled "lingual nerve margin" and holds a pink/tan soft tissue fragment that measures 0.5 x 0.3 x 0.2 cm. The fragment is entirely frozen as FSD1,

Specimen E is received in one appropriately labeled container, additionally labeled "soft tissue, left face" and holds a red/tan soft tissue fragment that measures 0.6 x 0.4 x 0.3 cm. The fragment is entirely frozen as FSE1,

Specimen F is received in one appropriately labeled container, additionally labeled "proximal nerve margin" and holds a red/tan soft tissue fragment that measures 0.4 x 0.3 x 0.2 cm. The fragment is entirely frozen as FSF1,

Specimen G is received in one appropriately labeled container, additionally labeled "proximal inferior alveolar nerve margin"

[page 4 of 5]
and holds a red/tan soft tissue fragment that measures 0.8 x 0.4 x 0.3 cm. The fragment is entirely frozen as FSG1,

Specimen H is labeled "composite resection of left mandible and floor of mouth" and consists of an 8.3 cm (anterior/posterior) x 7.5 cm (superior/inferior) x 4.9 cm (medial/lateral) soft tissue excision of which on the lateral aspect is a 7.5 x 4.8 cm pink/tan skin, along the medial/superior aspect is a 5.9 x 4.2 x 0.2 cm tan/white mucosa and embedded centrally is an 8.7 x 3.5 x 1.0 cm left mandible.

Ulcerating through the central aspect of the mucosa and extending into the soft tissue is an ill-defined soft friable, focally hemorrhagic and necrotic gray/white mass (7.2 x 5.4 x 4.3 cm). The mass obliterates approximately 40% of the mandible and is from the following margins: distal mandibular margin (inked orange) 1.9 cm, posterior soft tissue margin (inked green) 0.5 cm, medial soft tissue margin (inked black) 0.1 cm, lateral soft tissue margin (inked blue) 0.1 cm and anterior soft tissue 0.3 cm. The mass is 0.2 cm from the 12, 3, 6 and 9 o' clock mucosal margins. The mass is 1.3 cm from the 12 o' clock skin margin, 1.1 cm from the 3 o' clock skin margin, 0.9 cm to the 6 o' clock skin margin, and 2.1 cm to the 9 o' clock skin margin.

Block Summary:

- H1 - Distal mandibular bone margin, en face, following decalcification
- H2 - 12 to 3 o' clock mucosal margin, en face
- H3 - 3 to 6 o' clock mucosal margin, en face
- H4 - 6 to 9 o' clock mucosal margin, en face
- H5 - 9 to 12 o' clock mucosal margin, en face
- H6 - 12 to 3 o' clock skin margin, en face
- H7 - 3 to 6 o' clock skin margin, en face
- H8 - 6 to 9 o' clock skin margin, en face
- H9 - 9 to 12 o' clock skin margin, en face
- H10-H11- Perpendicular of mass with posterior soft tissue margin
- H12 - Perpendicular mass with anterior soft tissue margin
- H13-H14- Perpendicular mass with lateral soft tissue margin
- H15 - Perpendicular mass with medial soft tissue margin
- H16 - Mass into central mandible following decalcification
- H17 - Ulcerated mucosa and underlying mass

Specimen I is labeled "left level 2" and is a 4.2 x 3.2 x 1.5 cm aggregate of cauterized yellow/tan fibrofatty tissue, dissected for lymph node candidates. Lymph node candidates up to 3.6 cm in greatest dimension are identified.

[page 5 of 5]
Block Summary:

I1 - Four lymph node candidates
I2 - Four lymph node candidates
I3-I5 - One lymph node candidate, sectioned
Tissue remains in formalin.

Specimen J is labeled "left level 3" and is a 3.8 x 3.2 x 1.2 cm aggregate of yellow/tan fibrofatty tissue, dissected for lymph node candidates. Lymph node candidates up to 1.5 cm in greatest dimension are identified.

Block Summary:

J1 - Four lymph node candidates
J2 - Three lymph node candidates
J3 - Remainder of fat,

Specimen K is labeled "left level 4" and consists of a 2.8 x 2.7 x 0.5 cm aggregate of yellow/tan fibrofatty tissue, dissected for lymph node candidates. Four lymph node candidates up to 1.4 cm in greatest dimension are identified.

Block Summary:

K1 - Two lymph node candidates
K2 - Two lymph node candidates
K3 - Remainder of fat,

Specimen L is labeled "left level 1B" and is a 0.7 x 0.6 x 0.4 cm pink/tan lymph node candidate with attached fat, bisected in L1,

Specimen M is labeled "left level 1A" and is a 4.2 x 2.4 x 1.1 cm fragment of cauterized fibrofatty tissue with focally adherent red/tan cauterized muscle. Lymph node candidates averaging 0.6 cm in greatest dimension are identified.

Block Summary:

M1 - Four lymph node candidates
M2-M3 - Remainder of fat and fibromuscular tissue,

Source: NCI Genomic Data Commons file 60f22b48-20d3-42a8-958d-860a62a9d0a2 (TCGA-BA-A6DF.CBC8D89E-426B-4C4C-9B89-368D1DEC1718.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).